Surgical pathology report (de-identified scan), TCGA case TCGA-FT-A3EE, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - University of Miami, specimen TCGA-FT-A3EE-01A (Primary Tumor).

[page 1 of 5]
RUN DATE:
RUN TIME:

PAGE 1

PATIENT:

AGE/SEX: 1/F

REG DR:

SPECIMEN ID:

- A. URETER - RIGHT DISTAL URETERAL MARGIN (FS),
- B. URETER - LEFT DISTAL URETERAL MARGIN (FS), C. URETHRA - URETHRA,
- D. LYMPH NODE - RIGHT PELVIC LYMPH NODE, E. URINARY BLADDER - BLADDER,
- F. LYMPH NODE - LEFT PELVIC LYMPH NODE

- A. RIGHT DISTAL URETERAL MARGIN:
- NEGATIVE FOR CARCINOMA.
- B. LEFT DISTAL URETERAL MARGIN:
- NEGATIVE FOR CARCINOMA.
- C. URETHRA:
- INVASIVE HIGH GRADE UROTHELIAL CARCINOMA (PRIOR WHO 3 OF 3).
- THE TUMOR IS PRESENT AT THE CAUTERIZED RESECTION MARGIN.
- LYMPHATIC INVASION IS PRESENT.
- D. RIGHT PELVIC LYMPH NODE:
- NEGATIVE FOR CARCINOMA, FOUR LYMPH NODES (0/4).
- E. BLADDER (CYSTECTOMY AND BILATERAL SALPINGOOPHORECTOMY):
BLADDER
- INVASIVE, HIGH GRADE UROTHELIAL CARCINOMA, (PRIOR WHO GRADE 3 OF 3), 5 CM.
- THE TUMOR INVADES THE PERIVESICAL ADIPOSE TISSUE AND EXTENDS THROUGH THE SOFT TISSUE OF THE BLADDER NECK AND URETHRA INVOLVING THE VAGINAL WALL AND VAGINAL MUCOSA.
- LYMPHOVASCULAR AND PERINEURAL INVASION ARE PRESENT.
- THE NEOPLASM IS PRESENT AT THE CAUTERIZED CIRCUMFERENTIAL RESECTION MARGIN IN THE BLADDER NECK REGION. REMAINING RESECTION MARGINS ARE NEGATIVE.

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call and
return the report to us by mail.

1CD-0-3

carcinoma, urothelial, Nos 8120/3

Path Site: bladder, Nos C67.9

CQCF bladder, neck C67.5

hw 10/26/11

[page 2 of 5]
RUN DATE:
RUN TIME:

PAGE 2

Continued)

*** FINAL DIAGNOSIS *** (Continued)

UTERUS, ADNEXA AND VAGINA.

- UROTHELAL CARCINOMA INVOLVES VAGINAL WALL AND VAGINAL MUCOSA.
- ENDOMETRIUM WITH CYSTIC ATROPHY.
- UNREMARKABLE OVARIES AND FALLOPIAN TUBES.

F. LEFT PELVIC LYMPH NODE:

- NEGATIVE FOR CARCINOMA, FOUR LYMPH NODES (0/4).

TUMOR SUMMARY:

SPECIMEN TYPE

- BLADDER

PROCEDURE:

- RADICAL CYSTECTOMY
- OTHER: HYSTERECTOMY/BILATERAL SALPINGO-OOPHORECTOMY

TUMOR SITE:

- TRIGONE
- RIGHT LATERAL WALL
- OTHER: BLADDER NECK, URETHRA, VAGINAL WALL

TUMOR SIZE

- GREATEST DIMENSION: 5 CM
- * ADDITIONAL DIMENSIONS: 3 X 2.2 CM.

HISTOLOGIC TYPE

- UROTHELIAL (TRANSITIONAL CELL) CARCINOMA

HISTOLOGIC GRADE

- UROTHELIAL CARCINOMA (WHO 2004/ISUP)
- HIGH-GRADE

TUMOR CONFIGURATION:

- SOLID/NODULE
- ULCERATED

MICROSCOPIC TUMOR EXTENSION:

- PERIVESICAL FAT
- VAGINA
- URETHRA

MARGINS

- MARGIN INVOLVED BY INVASIVE CARCINOMA: CIRCUMFERENTIAL MARGIN AT BLADDER NECK AND URETHRA.

LYMPH-VASCULAR INVASION:

- PRESENT

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call and
return the report to us by mail.

[page 3 of 5]
RUN DATE:

RUN TIME:

Continued)

*** FINAL DIAGNOSIS *** (Continued)

PATHOLOGIC STAGING (pTNM)

- PRIMARY TUMOR (pT): pT4a
- REGIONAL LYMPH NODES (pN): pN0
- NUMBER EXAMINED: 8
- NUMBER INVOLVED: 0
- DISTANT METASTASIS (pM): NOT APPLICABLE

AJCC Classification (7th ed): pT4a, N0, M0

CLINICAL HISTORY-

PRE-OP DX: BLADDER CARCINOMA

PROCEDURE: RADICAL CYSTECTOMY WITH URINARY DIVERSION

RELEVANT CLINICAL HX: BLADDER CARCINOMA

GROSS DESCRIPTION:

- A. RECEIVED FRESH "RIGHT DISTAL URETERAL MARGIN FOR FROZEN". CONSISTS OF A SEGMENT OF PALE TAN SOFT TISSUE, 0.5 X 0.4 X 0.2 CM. THE SPECIMEN IS SUBMITTED IN TOTO IN ONE CASSETTE FOR FROZEN.
- B. RECEIVED FRESH "LEFT DISTAL URETERAL MARGIN". CONSISTS OF PALE TAN SOFT TISSUE, 0.5 X 0.5 X 0.2 CM. SUBMITTED IN TOTO IN ONE CASSETTE FOR FROZEN.
- C. RECEIVED IN FORMALIN "URETHRA". CONSISTS OF MULTIPLE FRAGMENTS OF TAN-GRAY, SOFT TISSUE, RANGING IN SIZE FROM 0.9 TO 3.5 CM. THE SPECIMEN IS RECEIVED UNORIENTED. REPRESENTATIVE SECTIONS SUBMITTED IN FOUR CASSETTES.
- D. RECEIVED IN FORMALIN "RIGHT PELVIC LYMPH NODES". CONSISTS OF TWO SEGMENTS OF TAN-YELLOW FIBROADIPOSE TISSUE, MEASURING 3.5 X 2 X 1 CM AND 2.5 X 1.3 X 0.7 CM. FOUR POSSIBLE LYMPH NODES. CASSETTES AS FOLLOWS:
- 1 TWO LYMPH NODES LARGEST ONE BISECTED
- 2&3 ONE LYMPH NODE BISECTED PER CASSETTE
- E. RECEIVED IN FORMALIN "BLADDER FOR FROZEN". CONSISTS OF A BLADDER WITH ATTACHED UTERUS, BILATERAL OVARIES AND FALLOPIAN TUBES. THE BLADDER MEASURES 14 X 12 X 4 CM. THE ATTACHED ADIPOSE TISSUE IS GROSSLY UNREMARKABLE. A TAN-GRAY ILL-DEFINED MASS IS

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call _____ and
return the report to us by mail.

[page 4 of 5]
ntinued)

GROSS DESCRIPTION: (Continued)

IDENTIFIED IN THE REGION OF THE URETHRA. THIS FIBROTIC MASS APPEARS TO REPLACE ENTIRELY THE SOFT TISSUE AROUND THE URETHRA AND EXTENDS INTO THE REGION OF THE TRIGONE. THE RIGHT URETER OS IS OBSTRUCTED BY A TAN-WHITE PAPILLARY LESION THAT MEASURES 2.5 X 2.5 CM. THE FIBROTIC MASS IN THE REGION OF THE URETHRA MEASURES 4 X 3.5 X 2.5 CM. THIS FIBROTIC MASS IS ADJACENT INTO THE VAGINAL MUCOSA. ON SERIAL SECTIONS BOTH DESCRIBED LESIONS APPEAR TO BE PART OF ONE TUMORAL MASS THAT EXTENDS UNDER THE MUCOSA FROM THE RIGHT URETER OS TO THE DISTAL URETHRAL-SOFT TISSUE RESECTION MARGIN AND MEASURES 5 X 3 X 2.2 CM AND INVADES THE MUSCLE AND THE PERIVESICLE ADIPOSE TISSUE. THE MASS COMES WITHIN 0.4 CM FROM THE INKED PERIVESICLE ADIPOSE TISSUE AND IS PRESENT AT THE INKED RESECTION CIRCUMFERENTIAL RESECTION MARGIN IN THE BLADDER NECK REGION. THE UTERUS MEASURES 6 CM FROM CERVIX TO FUNDUS, 5 CM CORNU TO CORNU AND 2 CM IN ANTERO-POSTERIOR DIAMETER. THE RIGHT FALLOPIAN TUBE, 7 CM IN LENGTH BY 0.5 CM IN DIAMETER. THE LEFT OVARY, 2 X 1 X 0.6 CM. THE LEFT FALLOPIAN TUBE, 7 CM IN LENGTH BY 0.5 CM IN DIAMETER. THE LEFT OVARY MEASURES 1.8 X 1 X 0.5 CM. THE UTERUS, OVARY AND FALLOPIAN TUBES ARE GROSSLY UNREMARKABLE. REPRESENTATIVE SECTIONS SUBMITTED AS FOLLOWS:

- 1 TUMOR IN RELATION TO CLOSEST CIRCUMFERENTIAL MARGIN AT PERIVESICAL FAT
- 2 FIBROTIC MASS IN RELATION TO VAGINAL WALL
- 3-8 ADDITIONAL REPRESENTATIVE SECTIONS OF TUMOR
- 9&10 COMPOSITE SECTION OF TUMOR FROM URETERAL OS TO BLADDER NECK SURROUNDING THE URETHRA
- 11&12 ADDITIONAL SECTIONS OF THE FIBROTIC AREA OF THE TUMORAL MASS
- 13 REPRESENTATIVE SECTIONS OF UNREMARKABLE FUNDUS
- 14 REPRESENTATIVE SECTIONS OF UNREMARKABLE LEFT BLADDER WALL
- 15 SECTION OF FIBROTIC MASS IN RELATION TO CERVIX
- 16 ANTERIOR AND POSTERIOR ENDOMETRIUM
- 17 RIGHT OVARY AND FALLOPIAN TUBE
- 18 LEFT OVARY AND FALLOPIAN TUBE

F. RECEIVED IN FORMALIN ARE TWO FRAGMENTS OF ????? FIBROADIPOSE TISSUE, 5 X 2 X 1 CM AND 3 X 2 X 0.8 CM. THE NATURE OF THE SPECIMEN REVEAL MULTIPLE POSSIBLE LYMPH NODES. CASSETTES AS FOLLOWS:

- 1 TWO LYMPH NODES IN TOTO
- 2&3 ONE LYMPH NODE PER CASSETTE

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call , and
return the report to us by mail.

[page 5 of 5]
RUN DATE:
RUN TIME:

PAGE 5

Continued)

OPERATING ROOM CONSULT (FS-CYT)
AFS/BFS: NEGATIVE FOR CARCINOMA.

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call / and
return the report to us by mail.

Source: NCI Genomic Data Commons file c6601d8d-6141-4003-848f-78e4213b8b22 (TCGA-FT-A3EE.5F7AEE5D-7F5F-495F-B497-31BDDCF1D338.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).